Somatic mutation profile of tumor specimen TCGA-OR-A5KX-01A (aliquot TCGA-OR-A5KX-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KX, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 25.5 years (9,298 days).
Specimen TCGA-OR-A5KX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d108bf20-b5f3-4ac3-a0b2-44da2d96aacf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KX-10A (Blood Derived Normal), aliquot TCGA-OR-A5KX-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eac8272-2802-40fc-ac43-abefcf455c95

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Frame Shift Del 4, Nonsense Mutation 1, RNA 1, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTC1 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060499752, CM1512580; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AL713999.2 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 165/244 reads (68%) | catalogued as rs1267568435; called by muse, mutect2, varscan2
- ENPP2 | c.1961G>A p.R654Q (on ENST00000075322 / NM_001040092.3; = p.R706Q on NM_006209.5) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753919036, COSV50011606; called by muse, mutect2
- FADD | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57229673; called by muse, varscan2
- FBN2 | c.1385C>A p.P462H | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV52550996; called by muse, mutect2, varscan2
- FRMD7 | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV53745895; called by muse, mutect2
- KRT6A | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 151/283 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as rs372637888; called by muse, mutect2, varscan2
- LAMA1 | c.3616G>A p.A1206T | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs202168119, COSV67531712; called by muse, mutect2, varscan2
- LAT2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs782720726, COSV51921118; called by muse, mutect2, varscan2
- N4BP2L2 | c.2159C>G p.S720C (on ENST00000674422; = p.S291C on NM_033111.4) | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1384658759; called by muse, mutect2
- NUP160 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.398); catalogued as rs1432565883; called by muse, mutect2
- PRDX2 | c.512-3_512-2del p.X171_splice | Splice Site (DEL) | VAF 14/143 reads (10%) | catalogued as rs765936562; called by pindel, varscan2
- SMC4 | c.2940G>C p.E980D | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs1217822603; called by muse, mutect2
- SPIN2B | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 365/1216 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs1162438963; called by muse, varscan2
- UNC13B | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773300549, COSV65931190; called by muse, mutect2, varscan2
- ZFP64 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV53798597; called by muse, mutect2, varscan2
- ACSL3 | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CACNA2D1 | c.2988_2989del p.C996Wfs*23 (on ENST00000356253 / NM_001366867.1; = p.C984Wfs*23 on NM_000722.4) | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by pindel, varscan2
- CHCHD4 | c.172_173del p.G58Nfs*11 (on ENST00000396914 / NM_001098502.2; = p.G71Nfs*11 on NM_144636.3) | Frame Shift Del (DEL) | VAF 77/222 reads (35%) | called by mutect2, pindel, varscan2
- GPR137 | c.1172_1197del p.Q391Pfs*12 | Frame Shift Del (DEL) | VAF 41/119 reads (34%) | called by mutect2, pindel, varscan2
- GUCY2F | c.2738A>T p.Y913F | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HDAC1 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- KIF26B | c.5642C>T p.P1881L | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYH4 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NECTIN3 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2
- NOTCH3 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SEL1L | c.1131T>G p.V377= | Splice Region (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 61/900 reads (7%) | called by muse, mutect2
- TOR1AIP2 | c.580_581del p.Q194Kfs*6 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by pindel, varscan2
- TTLL5 | c.1718A>C p.Q573P | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- AHNAK2 | c.14340A>G p.E4780= | Silent (SNP) | VAF 76/228 reads (33%) | catalogued as rs765173816; called by muse, mutect2, varscan2
- BRF2 | c.726G>A p.R242= | Silent (SNP) | VAF 51/680 reads (8%) | catalogued as COSV55105778; called by muse, mutect2
- DDRGK1 | c.327G>A p.A109= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as rs148502836; called by muse, mutect2, varscan2
- MAG | c.1263C>T p.C421= | Silent (SNP) | VAF 146/199 reads (73%) | catalogued as rs200957534, COSV62700642; called by muse, mutect2, varscan2
- MFF | c.144G>A p.R48= | Silent (SNP) | VAF 65/389 reads (17%) | catalogued as COSV58825613; called by muse, mutect2, varscan2
- NID2 | c.1077C>T p.S359= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs754437150; called by muse, mutect2, varscan2
- NOP2 | c.837C>T p.S279= (on ENST00000322166 / NM_001258308.2; = p.S275= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- OBSCN | c.22353C>T p.F7451= | Silent (SNP) | VAF 75/320 reads (23%) | catalogued as rs1233067474; called by muse, mutect2, varscan2
- TGFBR1 | c.522T>A p.G174= | Silent (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.1792C>T | RNA (SNP) | VAF 89/202 reads (44%) | called by muse, mutect2, varscan2
- CDKL1 | c.293+964G>A | Intron (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
